Gene-level copy-number profile of tumor specimen TCGA-29-2428-01A from TCGA case TCGA-29-2428, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 58.6 years (21,392 days).
Specimen TCGA-29-2428-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.fcfc7f2d-e53d-43e1-9838-fcc8c6525a6a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-29-2428-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/14f9e158-f517-47cc-8146-f2c6fcd76008

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 71; copy number 2: 24,107; copy number 3: 14,695; copy number 4: 17,357; copy number 5: 1,627; copy number 6: 1,114; copy number 7: 784; copy number 8: 38; copy number 12: 15; copy number 13: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-29-2428-01): tumor purity 0.78, ploidy 3.17, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:116,850,277–116,850,367, 1 gene: MIR4447.
- chr4:181,237,358–181,700,142, 5 genes: AC019235.1, LINC02500, AC093840.1, AC093840.2, AC084741.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,583 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:112,956,415–156,248,117, 791 genes, copy number 5–12 (within-gene range 3–12) (broad region; genes not listed).
- chr3:96,566,357–117,139,389, 297 genes, copy number 5–6 (within-gene range 0–6) (broad region; genes not listed).
- chr3:117,026,698–136,752,403, 403 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr3:167,683,298–198,222,513, 609 genes, copy number 6–13 (broad region; genes not listed).
- chr6:112,236,806–113,140,870, 14 genes, copy number 5 (within-gene range 2–5): AL365214.2, AL365214.1, RFPL4B, RPSAP45, KRT18P65, FEM1AP3, AL365214.3, AL357514.1, PA2G4P5, AL360085.1, RNU6-1163P, AL360015.1, FCF1P10, AL049695.1.
- chr8:100,475,667–100,663,415, 6 genes, copy number 6 (within-gene range 4–6): AP000424.1, AP000424.2, ANKRD46, GAPDHP62, SNX31, AP001205.1.
- chr10:44,712–1,132,384, 22 genes, copy number 6: AL713922.1, TUBB8, IL9RP2, ZMYND11, AL713922.2, RNA5SP297, DIP2C, RNA5SP298, RN7SL754P, AL669841.1, AL358216.1, MIR5699, PRR26, AL157709.1, LARP4B, AL359878.2, AL359878.1, GTPBP4, IDI2, IDI2-AS1, IDI1, WDR37.
- chr10:95,594,598–95,877,266, 4 genes, copy number 6 (within-gene range 4–6): RPS3AP36, ALDH18A1, TCTN3, ENTPD1.
- chr10:102,461,881–102,845,473, 13 genes, copy number 6 (within-gene range 4–6): ACTR1A, AL121928.1, SUFU, RPL23AP58, RNU6-43P, AL391121.1, TRIM8, ARL3, SFXN2, WBP1L, RNU6-1231P, CYP17A1, PFN1P11.
- chr12:27,022,546–27,972,733, 31 genes, copy number 6–8: MED21, AC092747.4, C12orf71, AC092747.3, AC092747.1, AC092747.2, STK38L, ARNTL2, ARNTL2-AS1, SMCO2, RARS1P1, PPFIBP1, AC087257.1, AC087257.2, AC009509.3, AC009509.1, REP15, AC009509.4, HMGB1P49, AC009509.2, MRPS35, Y_RNA, MANSC4, AC009511.2, KLHL42, AC009511.1, RN7SKP15, AC009511.3, AC008011.1, PTHLH, AC008011.2.
- chr12:28,163,298–28,236,828, 4 genes, copy number 6: AC022364.1, AC022364.2, AC022079.2, AC022079.1.
- chr12:124,593,181–124,935,895, 11 genes, copy number 6: AC073592.8, AC073592.2, AC073592.10, AC073592.4, AC073593.1, SCARB1, AC073593.2, RNU6-927P, UBC, MIR5188, RPL22P19.
- chr13:25,095,868–76,014,501, 719 genes, copy number 5–6 (broad region; genes not listed).
- chr13:76,552,807–114,337,626, 490 genes, copy number 5–6 (broad region; genes not listed).
- chr14:21,918,188–22,509,406, 82 genes, copy number 5 (broad region; genes not listed).
- chr14:49,057,713–49,374,383, 2 genes, copy number 5: AL110505.1, ATP5MC2P2.
- chr16:70,802,084–71,230,722, 4 genes, copy number 5 (within-gene range 2–5): HYDIN, RNU6ATAC25P, AC138625.2, AC138625.1.
- chr17:39,868,202–40,999,906, 63 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr20:57,266,797–57,712,780, 18 genes, copy number 6 (within-gene range 4–6): AL122058.1, Y_RNA, MIR4325, RPL39P39, SPO11, RAE1, MTND1P9, MTRNR2L3, RBM38-AS1, RBM38, AL109955.1, HMGB1P1, CTCFL, PCK1, AL035541.1, ZBP1, PMEPA1, NKILA.

Autosomal genes at a single copy (total copy number 1): 71. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
